CPTAC case C3N-02436 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e37fddac-49ed-4611-9638-49db1ffb5e66

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 51.8 years (18,937 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,732 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,732 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Indeterminate.

Follow-up (5 entries)
- Days to follow up: 332 days; Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 740 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,103 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,502 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,732 days (4.7 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 121.56 kg; Height: 160.02 cm; BMI: 47.47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02436-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 268 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02436-21: Section location: entire endomtetrial cavity; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-02436-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 502 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02436-22: Section location: entire endomtetrial cavity; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-02436-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 282 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02436-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 630 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02436-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02436-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 33 days; Method of sample procurement: Blood Draw.
